Somatic mutation profile of tumor specimen ALCH-ADNO-TTP1-A (aliquot ALCH-ADNO-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADNO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,737 days).
Specimen ALCH-ADNO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d88a6fe3-8103-492a-8e2c-71e964ca67bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADNO-NB1-A (Blood Derived Normal), aliquot ALCH-ADNO-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/535b3c63-d253-48d6-a4dd-76be216e055b

The open-access MAF lists 83 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 18, Nonsense Mutation 5, Intron 4, 5'UTR 3, Splice Site 2, Frame Shift Del 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 158/644 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BPIFB2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs770303903; called by muse, mutect2, varscan2
- CHST11 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 16/376 reads (4%) | catalogued as COSV57985987; called by muse, mutect2
- CHST3 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs371091098, COSV100910542; called by muse, mutect2, varscan2
- DDX11 | c.2516G>A p.R839H (on ENST00000545668 / NM_152438.2; = p.V791I on NM_004399.3) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.188); catalogued as rs755347093; called by muse, mutect2, varscan2
- DOCK2 | c.3685G>T p.D1229Y | Missense Mutation (SNP) | VAF 79/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56959162; called by muse, mutect2, varscan2
- DSG1 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 149/1057 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs778198305, COSV57133498; called by muse, mutect2, varscan2
- ENTPD8 | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV58164035; called by muse, mutect2, varscan2
- EPB41 | c.1944+1G>T p.X648_splice (on ENST00000343067 / NM_001166005.2; = p.X439_splice on NM_203342.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 58/367 reads (16%) | catalogued as rs1477424620, COSV58045962; called by muse, mutect2, varscan2
- GPR17 | c.244T>C p.W82R | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs764403175; called by muse, mutect2, varscan2
- IGKV3-20 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 217/904 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs921893458; called by muse, varscan2
- IRGC | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1276048918, COSV99746210; called by muse, mutect2, varscan2
- KCNT1 | c.1637G>T p.R546L (on ENST00000488444; = p.R565L on NM_020822.3) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as rs769855266, COSV53698868; called by muse, mutect2, varscan2
- MGAM | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 46/411 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs782165691, COSV71885403; called by muse, mutect2, varscan2
- MPPED1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1220280251; called by muse, mutect2
- OR8I2 | c.467C>A p.S156* | Nonsense Mutation (SNP) | VAF 142/457 reads (31%) | catalogued as COSV56168001, COSV56168420; called by muse, mutect2, varscan2
- PAPPA2 | c.4719G>T p.K1573N | Missense Mutation (SNP) | VAF 58/478 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1312409474, COSV99056647; called by muse, mutect2, varscan2
- RABL2B | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100711490; called by muse, mutect2, varscan2
- RBM10 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV61310641; called by muse, varscan2
- RBM20 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1266130657; called by muse, mutect2, varscan2
- RYR1 | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 24/185 reads (13%) | catalogued as COSV62110079; called by muse, mutect2, varscan2
- SSH2 | c.2858C>T p.T953I | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs762300811; called by muse, mutect2, varscan2
- STARD13 | c.1798C>T p.P600S (on ENST00000336934 / NM_001243476.3; = p.P482S on NM_052851.3) | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770183382; called by muse, mutect2, varscan2
- TRIM3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as rs757593762, COSV61985581; called by muse, mutect2, varscan2
- ZNF207 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1350018266; called by muse, mutect2
- ZNF431 | c.1053A>C p.K351N | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747668357; called by muse, mutect2, varscan2
- A1BG | c.233_236dup p.H79Qfs*9 | Frame Shift Ins (INS) | VAF 29/234 reads (12%) | called by mutect2, pindel, varscan2
- ATG7 | c.938del p.G313Dfs*5 | Frame Shift Del (DEL) | VAF 34/276 reads (12%) | called by mutect2, pindel, varscan2
- BUD23 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C6orf118 | c.910del p.E304Sfs*23 | Frame Shift Del (DEL) | VAF 62/268 reads (23%) | called by mutect2, pindel, varscan2
- CCDC9B | c.412A>G p.R138G | Missense Mutation (SNP) | VAF 21/285 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CIZ1 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.263); called by muse, mutect2
- COL22A1 | c.774G>C p.L258F | Missense Mutation (SNP) | VAF 82/558 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CPEB3 | c.1378A>T p.S460C | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTNNA2 | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DAAM2 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAT4 | c.8417A>T p.N2806I | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1D-8 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 60/594 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPDU1 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 100/784 reads (13%) | called by muse, varscan2
- NHSL1 | c.2084G>T p.C695F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- OR1L8 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PLEKHG3 | c.537C>A p.H179Q (on ENST00000394691; = p.H235Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PPP1R3F | c.575G>C p.C192S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.078); called by muse, varscan2
- PRKAG1 | c.892C>G p.H298D | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKD1 | c.1222A>T p.R408W | Missense Mutation (SNP) | VAF 21/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRB | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- RANBP2 | c.6855T>A p.N2285K | Missense Mutation (SNP) | VAF 106/992 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- RBM10 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, varscan2
- SERPINB3 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 122/428 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- SLC24A2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMARCAL1 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 91/805 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SSPN | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST6GALNAC3 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 22/156 reads (14%) | PolyPhen benign (0.158); called by muse, mutect2
- STXBP4 | c.764-3_768del p.X255_splice | Splice Site (DEL) | VAF 59/185 reads (32%) | called by mutect2, pindel, varscan2
- TRIM37 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2
- ZNF497 | c.1390C>T p.H464Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF716 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 41/302 reads (14%) | called by muse, mutect2, varscan2
- AKR1B10 | c.414C>T p.F138= | Silent (SNP) | VAF 60/253 reads (24%) | called by muse, mutect2, varscan2
- AL645922.1 | c.1041A>G p.Q347= | Silent (SNP) | VAF 153/516 reads (30%) | catalogued as rs772018952; called by muse, mutect2, varscan2
- ARSF | c.123T>A p.G41= | Silent (SNP) | VAF 17/430 reads (4%) | called by muse, mutect2
- COX8A | c.156C>T p.L52= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- CSNK1D | c.87T>C p.I29= | Silent (SNP) | VAF 142/1319 reads (11%) | catalogued as rs1343592966; called by muse, mutect2, varscan2
- GTDC1 | c.999G>A p.E333= | Silent (SNP) | VAF 46/203 reads (23%) | catalogued as COSV53999825; called by muse, mutect2, varscan2
- IL12RB1 | c.1959G>A p.E653= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as COSV101651920; called by muse, mutect2
- KIAA1217 | c.1377G>A p.P459= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as rs768656660, COSV100286146; called by muse, mutect2, varscan2
- MFGE8 | c.309G>A p.P103= | Silent (SNP) | VAF 95/266 reads (36%) | catalogued as rs535451948; called by muse, mutect2, varscan2
- MYT1L | c.774T>C p.V258= | Silent (SNP) | VAF 64/460 reads (14%) | called by muse, mutect2, varscan2
- NR5A2 | c.1071C>A p.V357= (on ENST00000367362 / NM_205860.3; = p.V311= on NM_003822.5) | Silent (SNP) | VAF 40/255 reads (16%) | catalogued as COSV52648254, COSV99370685; called by muse, mutect2
- PCDHA3 | c.1536G>A p.A512= | Silent (SNP) | VAF 63/584 reads (11%) | catalogued as COSV63541157; called by muse, mutect2, varscan2
- RYR1 | c.8415C>T p.Y2805= | Silent (SNP) | VAF 29/285 reads (10%) | called by muse, mutect2, varscan2
- RYR1 | c.11367A>T p.T3789= | Silent (SNP) | VAF 58/453 reads (13%) | called by muse, mutect2, varscan2
- SCTR | c.243G>T p.P81= | Silent (SNP) | VAF 73/284 reads (26%) | catalogued as COSV50027953; called by muse, mutect2, varscan2
- SERPIND1 | c.612G>A p.K204= | Silent (SNP) | VAF 66/567 reads (12%) | catalogued as rs1380552059; called by muse, mutect2, varscan2
- TINAGL1 | c.555C>T p.S185= | Silent (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- UGT2B4 | c.987C>A p.A329= | Silent (SNP) | VAF 59/573 reads (10%) | called by muse, mutect2, varscan2
- CASP1 | c.-3G>C | 5'UTR (SNP) | VAF 45/531 reads (8%) | called by muse, mutect2
- DPYSL2 | c.-51G>T | 5'UTR (SNP) | VAF 104/488 reads (21%) | called by muse, varscan2
- GUCY2EP | n.1603A>C | RNA (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- GYG1 | c.482-17A>G | Intron (SNP) | VAF 64/358 reads (18%) | called by muse, mutect2, varscan2
- IGHV3-64 | c.-15G>T | 5'UTR (SNP) | VAF 41/300 reads (14%) | called by muse, mutect2, varscan2
- MBD2 | c.702+1975T>G | Intron (SNP) | VAF 22/520 reads (4%) | called by muse, mutect2
- MPDU1 | c.388+37C>T | Intron (SNP) | VAF 63/433 reads (15%) | called by muse, varscan2
- SPG7 | c.377-49_377-43del | Intron (DEL) | VAF 48/484 reads (10%) | called by mutect2, pindel, varscan2
